Surgical pathology report (de-identified scan), TCGA case TCGA-F2-A44G, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-A44G-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, segment 2, biopsy

- Liver with no tumor seen, cholestasis

B: Liver, segment 3, biopsy

- Liver with no tumor seen, cholestasis

C: Liver, segment 4, biopsy

- Liver with small hyalinized granuloma, no tumor seen

D: Liver, segment #2, biopsy

- Liver with no tumor seen, cholestasis

E: Liver, left, biopsy

- Liver with small hyalinized nodule and parenchymal cholestasis, no tumor seen

ICD-O-3

F: Pancreatic duct margin, biopsy

- Bile duct with no tumor seen

adenocarcinoma, NOS

8140/3

G: Bile duct margin, biopsy

- Bile duct with no tumor seen

Site: pancreas, head

C25.0

H: Gallbladder, cholecystectomy

- Gallbladder with autolysis, no tumor seen

8123/12

R0

I: Lymph node, portal, biopsy

- Metastatic adenocarcinoma involving 1 of 1 lymph node (1/1)

- Size of metastasis 2 mm, with extranodal extension of tumor identified

J: Pancreaticoduodenectomy, Whipple procedure

Tumor Histologic Type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor size: 3.5 cm

Extent of invasion:

Peripancreatic soft tissues: Involved with tumor

Duodenum: Involved with tumor

Ampulla: Involved with tumor

ICD-O Discrepancy		X
Qual/Syn: Synchronous Primary Mtd		X

[page 2 of 6]
Lymphatic Invasion: Present

Venous Invasion: Not identified

Perineural Invasion: Present

Margins:

Pancreatic neck: En face pancreatic neck margin involved with tumor

Bile duct: Margin free of tumor

Peripancreatic soft tissues: Very close, <0.1 mm from tumor

Proximal (gastric): Free of tumor

Distal (duodenal): Free tumor

Regional lymph nodes (includes lymph nodes from specimens I and J):

Total number with metastasis: 3

Total number examined: 16

Additional pathologic findings: Focal atrophic changes and chronic pancreatitis

AJCC PATHOLOGIC TNM STAGE: pT3 pN1

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:

An intraoperative consultation is requested by

FSA1: Liver, segment 2, biopsy

- Liver with benign bile duct, no tumor seen

FSB1: Liver, segment 3, biopsy

- Liver with benign bile ducts, no tumor seen

FSC1: Liver, segment 4, biopsy

- Benign bile ducts and fibrous stroma, no tumor seen

FSD1: Liver, segment #2, biopsy

- Liver and benign bile ducts, no tumor seen

[page 3 of 6]
FSE1: Liver, left, biopsy
- Benign liver, no tumor seen

Drs. at

FSF1: Soft tissue, "pancreatic duct margin", biopsy
- No tumor seen.

FSG1: Soft tissue, "bile duct margin", biopsy
- No tumor seen.

Frozen Section Pathologist: ,

Clinical History:

-year-old with pancreatic cancer.

Gross Description:

Specimen A is received in an appropriately labeled container, additionally labeled "liver segment 2" and is a 6 x 5 x 5 mm pink//tan soft tissue fragment, totally submitted as FSA1,

Specimen B is received in an appropriately labeled container, additionally labeled "liver segment 3" and is a 3 x 3 x 2 mm pink//tan soft tissue fragment, totally submitted as FSB1,

Specimen C is received in an appropriately labeled container, additionally labeled "liver segment 4" and is an 8 x 6 x 4 mm pink//tan soft tissue fragment, totally submitted as FSC1,

Specimen D is received in an appropriately labeled container, additionally labeled "liver segment 3 #2" and is a 6 x 4 x 4 mm pink//tan soft tissue fragment, totally submitted as FSD1,

Specimen E is received in an appropriately labeled container, additionally labeled "left liver" and is a 5 x 4 x 2 mm pink//tan soft tissue fragment, totally submitted as FSE1,

Specimen F is received in an appropriately labeled container, additionally labeled "pancreatic duct margin" is a 3 x 3 x 2 mm pink/tan soft tissue fragment which is totally submitted as FSF1,

Specimen G is received in an appropriately labeled container, additionally labeled "bile duct margin" is a 1.0 x 0.4 x 0.4 cm segment of pink/tan soft tissue which has an identifiable lumen. This is totally submitted as FSG1,

[page 4 of 6]
Specimen H is labeled "gallbladder" and is an intact 11.5 x 5.4 x 4.2 cm gallbladder with attached stapled cystic duct. The serosa is smooth green/tan and glistening. The lumen is distended with dark green viscid bile and lined by a velvety dark green mucosa. The wall has a uniform thickness of 0.1 cm. Representative sections are submitted to include the cystic duct margin in blocks H1-H2. No stones are identified within the lumen.

Specimen I is labeled "portal node" and is a 2.4 x 1.3 x 0.6 cm gray/tan lymph node candidate, serially sectioned and submitted in I1.

Specimen J is labeled "pancreaticoduodenectomy."

Specimen fixation: formalin

Specimen type: standard Whipple

Organs received (Whipple Specimen): stomach (7.0 x 3.5 cm), head of pancreas (3.5 x 2.8 cm), common bile duct (2.4 cm long, diameter ranges from 0.2 to 0.6 cm complete)

Orientation: Inking: common bile duct=yellow, pancreatic body=blue, uncinate process=black, fatty pancreatic soft tissue=green, vessels (1.0 x 0.5 cm, complete), adjacent to the portal vein=red

Tumor location: head of the pancreas and possibly the common bile duct

Tumor dimensions: 3.5 x 2.1 x 2.0 cm

Gross appearance of tumor: yellow/white, solid; no areas of hemorrhage are identified, potential tumor necrosis at the center of the mass

Extent of invasion:

Confined / non-confined to the pancreas: non-confined

Involvement of the ampulla: possible (distal common bile duct is stenosed) (J8, complete)

Involvement of the duodenum: present

[page 5 of 6]
Involvement of the bile duct: possible (distal common bile is stenosed for the length of 1.2 cm and the proximal common bile duct is dilated with velvety, erythematous mucosa)

Involvement of adjacent vessels: The portal vein groove is smooth and intact, a 1.0 x 0.5 cm fragment of vessel is present posterior to the head of pancreas (section J4, complete)

Spleen (if applicable): n/a

Gallbladder (if applicable): n/a

Stomach (if applicable): grossly not involved

Surgical margins:

Pancreatic body: 0.9 cm

Uncinate (Retroperitoneal): less than 0.1 cm

Common Bile duct: 3.0 cm

Proximal margin (stomach): 4 cm

Distal margin (duodenum): 11 cm

Peripancreatic soft tissues: abuts multiple green inked soft tissue margins

Lymph nodes: submitted as per block summary

Other remarkable findings: There is a minimal amount of normal pancreatic parenchyma in the neck region of the pancreas.

Digital photograph taken: no

Tissue submitted for special investigation: tumor and normal submitted for Tissue Procurement Facility

Block summary:

(Inking: common bile duct=yellow, pancreatic body=blue, uncinate process=black, peripancreatic soft tissue=green, vessel (1.0 x 0.5 cm complete), adjacent to portal vein=red)

J1 - pyloric margin, representative sections

J2 - duodenal margin, representative sections

[page 6 of 6]
-
- J3 - pancreatic body margin, en face, include pancreatic duct
- J4 - perpendicular section of uncinate margin with red inked vessel, adjacent to portal vein
- J5 - perpendicular section of uncinate process
- J6 - perpendicular section of uncinate, with green inked peripancreatic margin
- J7 - remainder of the uncinate process, en face
- J8 - ampulla
- J9-J10 - pancreatic tumor involving the duodenum
- J11 - section of the tumor with common bile duct and pancreatic duct
- J12 - normal pancreatic parenchyma, one bisected lymph node
- J13 - five lymph node candidates
- J14 - one lymph node candidate, bisected
- J15 - one lymph node candidate, serially sectioned

Source: NCI Genomic Data Commons file 1faf8bb3-7dcc-4692-8567-91ae5a4c5976 (TCGA-F2-A44G.65B052FE-569F-462F-881C-1AC795F9CC61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).